Surgical pathology report (de-identified scan), TCGA case TCGA-FD-A5BY, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site BLN - University Of Chicago, specimen TCGA-FD-A5BY-01A (Primary Tumor).

[page 1 of 3]
ICD-0-3

Carcinoma, Urothelial 8120/3

Gender: Female

Bladder, posterior wall C67.4

Race: White

QW 12/24/12

Pathology Report:

Surgical Pathology Report

FINAL PATHOLOGIC DIAGNOSIS

A. Scar tissue; excision:

- Skin and subcutaneous tissue with fibrosis, no tumor.

B. Right pelvic lymph nodes; lymphadenectomy:

- Eleven lymph nodes, no tumor (0/11).

C. Left pelvic lymph nodes; lymphadenectomy:

- Eight lymph nodes, no tumor (0/8).

D. Urinary bladder, urethra and piece of small bowel; cystectomy:

- Bladder with high grade urothelial carcinoma, invading thru the muscularis propria and into the perivesical tissue, see pathologic parameters.
- Benign ovarian tissue adjacent to right bladder wall, no tumor.
- Portion of intestinal wall, no tumor.
- All resection margins, free of tumor.

Urothelial Carcinoma Pathologic Parameters

1. Tumor type: Invasive urothelial carcinoma.
2. Grade of tumor: High grade.
3. Depth of invasion: Extravesicular soft tissue (microscopic).
4. Tumor distribution: Solitary, 2.4 cm, posterior wall.
5. Ureteral margins: Negative for tumor.
6. Distal urethral margin: Negative for tumor.
7. Soft tissue margin or serosa: Negative for tumor.
8. Lymph nodes: Negative for tumor (0/19).
9. pTNM: pT3a,N0,MX.

Effective _____ is Checklist utilizes the 7th edition TNM staging system for Bladder of the American Joint Committee on Cancer (AJCC) and the International Union Against Cancer (UICC).

[page 2 of 3]
xx

[], MD

Interpretation performed by the Attending Pathologist and reviewed with the Resident/Fellow, [], M.D.

Electronically Signed Out by [] MD

Clinical History:

Patient is a year-old female with high-grade urothelial carcinoma (invasive to the muscularis propria) undergoing cystectomy of an Indiana pouch.

Specimens Received:

A: Scar tissue

B: Right pelvic lymph nodes

C: Left pelvic lymph nodes

D: Bladder urethra and piece of small bowel

Gross Description:

The specimens are received in four containers each labeled with the patient's name and medical record number.

A. The first container is additionally identified as, "scar tissue". Received fresh and placed in formalin is an unoriented 14 x 2.5 cm ellipse of tan skin excised to a depth of 1.4 cm. There is a 5 cm linear scar on the skin surface and 2 linear defects on the skin surface measuring 0.2-0.6 cm. The deep margin is inked blue. The specimen is serially sectioned with representative section submitted as A1.

B. The second container is additionally identified as, "right pelvic lymph nodes". Received fresh and placed in formalin are multiple yellow-tan, lobulated, soft adipose tissue fragments, which form an aggregate measuring 7 x 4.2 x 1.8 cm. The specimen is dissected to reveal 14 lymph node candidates measuring 0.3-4.7 cm in greatest dimension. They are submitted as B1-B8.

B1: 5 lymph node candidates

B2: 4 lymph node candidates

B4: 4 lymph node candidates

B5-B10: 1 lymph node candidate, serially sectioned

B11: Fibroadipose tissue

C. The third container is additionally identified as, "left pelvic lymph nodes". Received fresh and placed in formalin are multiple yellow-tan, soft, lobulated adipose tissue fragments, which form an aggregate measuring 8.8 x 5.6 x 2.1 cm. The specimen is dissected to reveal 18 lymph node candidates ranging from 0.5-4.5 cm in greatest dimension. They are submitted as C1-C11.

[page 3 of 3]
C1: 6 lymph node candidates
C2: 4 lymph node candidates
C3: 3 lymph node candidates
C4: 2 lymph node candidates
C5: 1 lymph node candidate, bisected
C6: 1 lymph node candidate, bisected
C7-C11: 1 lymph node candidate, serially sectioned

D. The fourth container is additionally identified as, "bladder, urethra, piece of small bowel". Received fresh and place in formalin is a 202.2 g cystectomy specimen with overall measurements of 12.5 x 10.5 x 4.5 cm. the bladder portion measures 8 x 6 x 1.3 cm and the bowel mucosa measures 7.5 x 7 x 0.9 cm. There are 5 fragments of detached adipose tissue ranging in size from 2-8.5 x 1.8 x 0.4-0.7 cm and a portion of fibromembranous tissue measuring 10 x 3.3 x 1.8 cm. The interior wall of the bladder consists of bowel mucosa. A right ureteral stump is identified measuring 2 x 0.3 cm and demonstrates an intact patent lumen. The left ureter is not grossly identified. There is a 1.8 x 1 cm bladder wall defect in the lateral wall, a 3 x 1.5 cm bladder wall defect superiorly, and a 1.5 x 1 cm bladder wall defect adjacent to the tumor bed. The serosal surface shows yellow lobulated fibroadipose tissue with focal cautery artifact. The urethral margin and the outer surface of the bladder is inked black. The specimen is opened anteriorly to reveal a 2 x 1.8 cm white-tan, friable, ulceration with a hemorrhagic border located in posterior wall. On cut section, the white-tan, ill-defined, firm mass measures 2.4 x 1.2 x 0.7 and extends into the muscularis propria and abuts the deep margin. A gross photograph is taken. The surrounding bladder mucosa is edematous, wrinkled, pink-tan with a uniform 0.1 cm wall thickness.

Representative sections are submitted as follows:

D1: Distal urethral margin
D2: Right ureter resection margin
D3-D8: Bladder mass with ulceration (closest to deep margin in D5-D6)
D9: Uninvolved bladder mucosa posterior wall
D10: Uninvolved bladder mucosa left lateral wall, with possible left ureter margin
D11: Uninvolved bladder mucosa right lateral wall
D12-D15: Uninvolved anterior bowel mucosa wall

xxx

[] MD

Prior Malignancy History	thyroid	✓

Source: NCI Genomic Data Commons file 88da601e-d832-4ae5-bb88-43e1bc23d2c0 (TCGA-FD-A5BY.DE874063-9AE8-4855-8CD2-D30F71E3C167.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).